Surgical pathology report (de-identified scan), TCGA case TCGA-IE-A4EJ, project TCGA-SARC (Sarcoma), tissue source site ABS - IUPUI, specimen TCGA-IE-A4EJ-01A (Primary Tumor).

[page 1 of 2]
Operative Procedure:

Right thigh soft tissue sarcoma excision

Specimen Received:

Right thigh sarcoma; stitch is distal

Final Pathologic Diagnosis:

Soft tissue, right thigh, resection:

Pleomorphic undifferentiated sarcoma (8.5 cm in greatest dimension).

See Synoptic Report and Note below.

Synoptic Report

Procedure: Resection
Tumor site: Right thigh
Tumor size: 8.5 cm (greatest dimension)
Macroscopic extent of tumor: Intramuscular
Histologic type: Undifferentiated pleomorphic sarcoma
Mitotic rate: 5/10 high-power fields (HPF)
Necrosis: Not identified
Histologic grade: High grade
Margins: Sarcoma extends to peripheral margin

Pathologic staging (pTNM)

TNM descriptors: None known
Primary tumor (pT): pT2b: Tumor more than 5 cm in greatest dimension, deep tumor
Regional lymph nodes (pN): pNx Cannot be assessed
Distant metastasis (pM): pMx Cannot be assessed

Additional pathologic findings: None

Ancillary studies

Immunohistochemistry: Not performed
Cytogenetics: Not performed
Molecular Pathology: Not performed
Preresection treatment: No known therapy
Treatment effect: Not applicable

ICD-0-3

Sarcoma, pleomorphic 8802/3

Site: thigh, NOS C49.2

hw
9/25/10

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Gross Description:

The specimen is received in a single formalin filled container labeled with the patient name and "right thigh sarcoma, stitch is distal" and

[page 2 of 2]
consists of a portion of ovoid fibromuscular soft tissue that is 14.8 x 11.0 x 6.0 cm. There is a black stitch marking the distal aspect. This will be designated as 6 o'clock. The specimen has been previously incised one peripheral aspect. The specimen is inked as follows: the previously incised peripheral aspect is inked black and the opposite peripheral aspect in blue. Sectioning reveals a white-tan somewhat soft mass that is 8.5 x 6.0 x 4.5 cm. This lesion measures 4 cm from the distal aspect and 4.5 cm from the proximal aspect. The mass does not appear to be encapsulated; however the previously incised aspect of the specimen has an overlying fibrous band which does not appear to be penetrated by the tumor. Otherwise, the lesion does abut the fibrous band. The lesion is approximately 1 cm from the nearest not previously incised peripheral aspect. Representative sections are submitted as follows:

- 1 distal tip;
- 2 proximal tip;
- 3-10 representative sections of mass to include the black inked surface and blue inked surface.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Taken:

Gender: F

Source: NCI Genomic Data Commons file d9e0df72-9782-445b-8c2a-cdfd16d3a341 (TCGA-IE-A4EJ.223D6CAF-EC1D-4538-A14B-01FBB37453A4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).